Somatic mutation profile of tumor specimen PCProject_0215_T1_WES (aliquot PCProject_0215_T1_WES_1) from CMI case PCProject_0215, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 45.6 years (16,662 days).
Specimen PCProject_0215_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b9c8222-6899-4621-9a5a-88be765b4242.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0215_SALIVA (DNA), aliquot PCProject_0215_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d54afd06-303d-45e3-8e2e-e28b41ea91f3

The open-access MAF lists 39 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 9, Intron 3, Nonsense Mutation 3, 3'UTR 1, 5'Flank 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.305T>G p.F102C | Missense Mutation (SNP) | VAF 169/417 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920894, COSV61652830, COSV61654088, COSV61654168; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- AFF1 | c.3224G>A p.R1075H | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs140979415; called by muse, mutect2, varscan2
- AQP7 | c.454G>A p.V152I | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs76608797; called by muse, mutect2, varscan2
- ASPA | c.497C>A p.T166N | Missense Mutation (SNP) | VAF 170/501 reads (34%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as CM063847; called by muse, mutect2, varscan2
- CACNA1A | c.6728G>A p.R2243Q | Missense Mutation (SNP) | VAF 43/224 reads (19%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.598); catalogued as rs765309213; called by muse, mutect2, varscan2
- KRT23 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 30/389 reads (8%) | catalogued as rs370055839; called by muse, mutect2
- KRT40 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs779823166, COSV66696465; called by muse, mutect2, varscan2
- PDE3A | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.097); catalogued as rs755543591; called by muse, mutect2, varscan2
- RTN4RL1 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs567714935, COSV58675146; called by muse, mutect2
- ALG12 | c.1239-6C>T | Splice Region (SNP) | VAF 26/540 reads (5%) | called by muse, mutect2
- ATP6AP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 138/196 reads (70%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, varscan2
- ATRAID | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 183/520 reads (35%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- BHLHE41 | c.655C>G p.P219A | Missense Mutation (SNP) | VAF 57/285 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- CARD6 | c.981G>T p.W327C | Missense Mutation (SNP) | VAF 52/367 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HMGCS2 | c.1313T>G p.L438W | Missense Mutation (SNP) | VAF 241/598 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAST1 | c.1463T>A p.L488* | Nonsense Mutation (SNP) | VAF 28/324 reads (9%) | called by muse, mutect2
- MIPOL1 | c.1165A>T p.T389S | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MYC | c.329T>C p.M110T (on ENST00000377970; = p.M125T on NM_002467.6) | Missense Mutation (SNP) | VAF 67/199 reads (34%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- NUP214 | c.2996C>A p.A999E | Missense Mutation (SNP) | VAF 127/352 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SCN11A | c.709T>C p.S237P | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- SMU1 | c.394T>C p.Y132H | Missense Mutation (SNP) | VAF 78/214 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- USP35 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZBED8 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 75/495 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- ZBTB17 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 67/225 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZMYND8 | c.306C>A p.C102* (on ENST00000311275 / NM_001363741.2; = p.C122* on NM_012408.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/814 reads (13%) | called by muse, mutect2, varscan2
- AIRE | c.372G>A p.P124= | Silent (SNP) | VAF 55/237 reads (23%) | catalogued as rs775117249, COSV52393946; ClinVar: likely benign; called by muse, mutect2, varscan2
- GNAS | c.1461C>T p.V487= | Silent (SNP) | VAF 24/265 reads (9%) | catalogued as rs902506148; called by muse, mutect2
- GOLIM4 | c.336T>C p.S112= | Silent (SNP) | VAF 36/196 reads (18%) | called by muse, mutect2, varscan2
- LAMB1 | c.153G>A p.S51= | Silent (SNP) | VAF 29/213 reads (14%) | catalogued as rs1379984543; called by muse, mutect2, varscan2
- LTK | c.951C>T p.G317= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, varscan2
- MAP4K1 | c.1599G>A p.T533= | Silent (SNP) | VAF 18/240 reads (8%) | catalogued as rs772511208; called by muse, mutect2
- PCDHA1 | c.339G>A p.P113= | Silent (SNP) | VAF 167/453 reads (37%) | catalogued as COSV65376176, COSV65377373; called by muse, mutect2, varscan2
- RGS7 | c.87C>T p.D29= | Silent (SNP) | VAF 97/303 reads (32%) | catalogued as rs563733368, COSV58542082; called by muse, mutect2, varscan2
- TNN | c.57C>T p.L19= | Silent (SNP) | VAF 36/194 reads (19%) | called by muse, mutect2, varscan2
- MIR124-2 | chr8:64377488 A>T | 5'Flank (SNP) | VAF 21/351 reads (6%) | called by muse, mutect2
- NPAT | c.38-11136G>A | Intron (SNP) | VAF 59/152 reads (39%) | catalogued as rs1203157890; called by muse, mutect2, varscan2
- PIP5K1A | c.*83A>G | 3'UTR (SNP) | VAF 52/252 reads (21%) | called by muse, mutect2, varscan2
- SLC25A29 | c.79-2527G>A | Intron (SNP) | VAF 67/433 reads (15%) | catalogued as rs764229921; called by muse, mutect2, varscan2
- STARD5 | c.99+109C>A | Intron (SNP) | VAF 65/167 reads (39%) | called by muse, mutect2, varscan2
